Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A27V, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A27V-01A (Primary Tumor).

ICD-0-3
carcinoma, infiltrating lobular, NOS
site: breast, NOS C50.9 8520/3

5/19/11

page 1 / 1

original

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.: 1

Patient: XXX

PESEL: XXX

Age: 1

Gender: F

Material: Total organ resection – right breast

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis:

Revised/Amended		

Examination performed on

Macroscopic description:

Right breast sized 1.2 x 11.2 x 3.6 cm removed without axillary tissues and with a skin flap of 13.2 x 16.3 cm. Weight 200 g.

Tumour sized 3.2 x 1.8 x 2.8 cm on the boundary of outer quadrants, located 1.8 cm from the outer boundary, 0.3 cm from the base and 0 cm from the skin.

Microscopic description:

Carcinoma lobulare invasivum (classical type) - NHG2 (3+2+1: 0 mitoses/10 HPF - visual area: 0.55mm).

Infiltratio carcinomatosa cutis mammae.

Mamilla sine laesionibus.

Glandular tissue showing adenosis sclerosans et calcifications

Histopathological diagnosis:

(including Examination

Carcinoma lobulare invasivum mammae dextrae. Invasive lobular carcinoma of the right breast (NHG2, pT2, pN0/sn/).

Compliance validated by:

Source: NCI Genomic Data Commons file 707c9763-b744-4d39-83fb-7df5093c6916 (TCGA-D8-A27V.E5011BD1-E1DE-4A47-BF3C-66BA1E0B84DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).